Somatic mutation profile of tumor specimen ALCH-B2RX-TTP1-A (aliquot ALCH-B2RX-TTP1-A-1-0-D-A78Q-36) from ALCHEMIST case ALCH-B2RX, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 68.9 years (25,167 days).
Specimen ALCH-B2RX-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8138650e-1518-42a2-8470-4fba8631d770.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2RX-NB1-A (Blood Derived Normal), aliquot ALCH-B2RX-NB1-A-1-0-D-A78Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/770fbd6f-6f08-4695-af15-72b0e617c083

The open-access MAF lists 54 somatic variants for this specimen: 33 protein-altering or splice-affecting, 10 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 10, Intron 8, Nonsense Mutation 2, In Frame Del 2, Frame Shift Del 2, 5'Flank 1, 5'UTR 1, Splice Region 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CADM3 | c.1133C>T p.T378M (on ENST00000368125 / NM_001127173.3; = p.T412M on NM_021189.5) | Missense Mutation (SNP) | VAF 37/203 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757367378, COSV63674603; called by muse, mutect2, varscan2
- CNTN4 | c.135A>T p.K45N | Missense Mutation (SNP) | VAF 63/636 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.089); catalogued as COSV68580110; called by muse, mutect2, varscan2
- DOCK4 | c.2912T>C p.M971T | Missense Mutation (SNP) | VAF 22/605 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as rs1371904911; called by muse, mutect2
- EGFR | c.2237_2255delinsT p.E746_S752delinsV | In Frame Del (DEL) | VAF 102/657 reads (16%) | catalogued as rs727504258, COSV51765862; ClinVar: drug response; called by pindel, varscan2*
- EPHB2 | c.2365C>T p.P789S (on ENST00000400191 / NM_001309193.2; = p.P790S on NM_004442.7) | Missense Mutation (SNP) | VAF 118/369 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV65863099; called by muse, mutect2, varscan2
- FAM20B | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 91/415 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as rs758621344, COSV55382578; called by muse, mutect2, varscan2
- GNAS | c.782C>T p.S261L | Missense Mutation (SNP) | VAF 92/322 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.078); catalogued as rs1489957353, COSV58338436; called by muse, mutect2, varscan2
- ITGA2B | c.624+8G>A | Splice Region (SNP) | VAF 131/485 reads (27%) | catalogued as rs1423844831; called by muse, mutect2, varscan2
- JMJD6 | c.844A>G p.I282V | Missense Mutation (SNP) | VAF 89/379 reads (23%) | SIFT tolerated (0.56); PolyPhen benign (0.034); catalogued as rs765308944, COSV57973938; called by muse, mutect2, varscan2
- OR2L3 | c.794G>C p.R265P | Missense Mutation (SNP) | VAF 261/537 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV63454367; called by muse, mutect2, varscan2
- RASIP1 | c.1499C>T p.P500L | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as COSV55802203; called by muse, mutect2, varscan2
- TMTC1 | c.190C>T p.R64W | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as rs1342803650; called by muse, mutect2, varscan2
- TPTE | c.818A>G p.K273R (on ENST00000618007 / NM_199261.4; = p.K255R on NM_199259.4) | Missense Mutation (SNP) | VAF 70/775 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as rs1232536001; called by muse, mutect2
- WDR87 | c.6548G>A p.G2183E | Missense Mutation (SNP) | VAF 70/282 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs761411243; called by muse, mutect2, varscan2
- CATSPERB | c.1808C>G p.S603* | Nonsense Mutation (SNP) | VAF 26/472 reads (6%) | called by muse, mutect2
- CDC42EP1 | c.669_670del p.E223Dfs*76 | Frame Shift Del (DEL) | VAF 29/116 reads (25%) | called by pindel, varscan2
- CDK20 | c.621G>C p.K207N (on ENST00000325303 / NM_001039803.3; = p.K186N on NM_012119.4) | Missense Mutation (SNP) | VAF 24/145 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- CLASP2 | c.4490G>A p.R1497H (on ENST00000359576; = p.R1496H on NM_015097.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/290 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- DDX10 | c.2585A>T p.E862V | Missense Mutation (SNP) | VAF 89/318 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- DNAH9 | c.4337G>T p.G1446V | Missense Mutation (SNP) | VAF 13/415 reads (3%) | SIFT tolerated (0.35); PolyPhen benign (0.009); called by muse, mutect2
- FAT1 | c.2992A>T p.N998Y | Missense Mutation (SNP) | VAF 121/418 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- FERMT2 | c.1355A>G p.N452S | Missense Mutation (SNP) | VAF 30/187 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- HTR1A | c.409G>T p.A137S | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.822); called by muse, mutect2, varscan2
- ITPR2 | c.1837A>G p.K613E | Missense Mutation (SNP) | VAF 17/403 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.021); called by muse, mutect2
- MTRF1L | c.427A>G p.M143V | Missense Mutation (SNP) | VAF 68/297 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- MYOF | c.5338A>G p.I1780V | Missense Mutation (SNP) | VAF 10/254 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.038); called by muse, mutect2
- RNF19B | c.1210G>T p.G404* | Nonsense Mutation (SNP) | VAF 66/303 reads (22%) | called by muse, mutect2, varscan2
- SEC24B | c.3726G>T p.Q1242H | Missense Mutation (SNP) | VAF 195/741 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- SLC12A1 | c.1684+1del | Frame Shift Del (DEL) | VAF 24/193 reads (12%) | called by mutect2, pindel, varscan2
- TMEM169 | c.403C>G p.P135A | Missense Mutation (SNP) | VAF 103/619 reads (17%) | SIFT tolerated (0.59); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TMX2 | c.820A>G p.I274V | Missense Mutation (SNP) | VAF 124/413 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- TPRN | c.190_192del p.L64del | In Frame Del (DEL) | VAF 13/58 reads (22%) | called by pindel, varscan2
- TRAV10 | c.139A>G p.T47A | Missense Mutation (SNP) | VAF 108/495 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- DLGAP3 | c.825G>A p.A275= | Silent (SNP) | VAF 28/85 reads (33%) | catalogued as rs756223853; called by muse, mutect2, varscan2
- KEAP1 | c.384C>T p.I128= | Silent (SNP) | VAF 70/229 reads (31%) | catalogued as rs1404132954; called by muse, mutect2, varscan2
- KIF26B | c.2451C>T p.S817= | Silent (SNP) | VAF 13/68 reads (19%) | catalogued as rs773441087, COSV63654217; called by muse, mutect2
- KRT14 | c.363C>T p.N121= | Silent (SNP) | VAF 174/732 reads (24%) | catalogued as rs751443458; called by muse, mutect2
- MAP7 | c.936G>A p.R312= | Silent (SNP) | VAF 126/354 reads (36%) | called by muse, mutect2, varscan2
- MICU1 | c.1257C>G p.L419= (on ENST00000361114 / NM_001195518.2; = p.L425= on NM_006077.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 73/246 reads (30%) | catalogued as rs577512531; called by muse, mutect2, varscan2
- POLR3B | c.2334G>A p.T778= | Silent (SNP) | VAF 224/812 reads (28%) | catalogued as rs150800622; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR1 | c.6225G>A p.K2075= | Silent (SNP) | VAF 116/540 reads (21%) | catalogued as COSV62087388; called by mutect2, varscan2
- TRNT1 | c.27C>T p.H9= | Silent (SNP) | VAF 45/141 reads (32%) | catalogued as rs776254990, COSV99285649; ClinVar: likely benign; called by muse, mutect2, varscan2
- USP21 | c.681G>T p.L227= | Silent (SNP) | VAF 39/123 reads (32%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65502861 T>C | 5'Flank (SNP) | VAF 12/210 reads (6%) | called by muse, mutect2
- CD59 | c.170-1120C>G | Intron (SNP) | VAF 77/314 reads (25%) | called by muse, mutect2, varscan2
- CDK15 | c.1009+5808A>G | Intron (SNP) | VAF 12/321 reads (4%) | catalogued as COSV99643265; called by muse, mutect2
- DNPH1 | c.376+14G>A | Intron (SNP) | VAF 33/89 reads (37%) | catalogued as COSV52735034; called by muse, mutect2
- FSCN2 | c.*7G>T | 3'UTR (SNP) | VAF 21/69 reads (30%) | called by muse, mutect2, varscan2
- ISCU | c.419-11G>A | Intron (SNP) | VAF 105/640 reads (16%) | catalogued as rs761162296; called by muse, varscan2
- KDR | c.2615-16T>A | Intron (SNP) | VAF 19/504 reads (4%) | called by muse, mutect2
- KIF5A | c.2992+17G>C | Intron (SNP) | VAF 94/574 reads (16%) | called by muse, mutect2, varscan2
- NKIRAS2 | c.-218G>A | 5'UTR (SNP) | VAF 27/166 reads (16%) | catalogued as rs782101114, COSV100288765; called by muse, mutect2, varscan2
- POMT2 | c.1117-39T>A | Intron (SNP) | VAF 47/218 reads (22%) | catalogued as rs1169921587; called by muse, mutect2, varscan2
- TTN | c.10303+2594G>A | Intron (SNP) | VAF 97/652 reads (15%) | catalogued as rs184205694, COSV60168078; called by muse, mutect2, varscan2
